Surgical pathology report (de-identified scan), TCGA case TCGA-21-5784, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-5784-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

Clinical History/Diagnosis: Right Lung CA

Source of Specimen(s):

- 1: 11R Lymph Node
- 2: 3A Lymph Node
- 3: 10 R Lymph Node
- 4: Right upper lobe Lung, resection (segmental or lobe)
- 5: Level 7 Lymph Node
- 6: Level 10 Lymph Node
- 7: Level 4R Lymph Node

[REDACTED] TCGA-21-5784

Gross Description:

Received in seven parts.

Source of Tissue: 1. Labeled #1, "11R lymph node"

Gross Description: Received fresh labeled, 11R lymph node". It consists of multiple soft black-brown anthracotic lymph nodes measuring from 0.1 up to 0.5 cm in greatest dimension. The lymph nodes are entirely submitted in 1A-1B.

Source of Tissue: 2. Labeled #2, "3A lymph node"

Gross Description: Received fresh labeled, 3A lymph node". It consists of a soft black-brown anthracotic lymph node measuring 0.8 x 0.6 x 0.3 cm. The specimen is entirely submitted in 2A.

Source of Tissue: 3. Labeled #3, "10R lymph node"

Gross Description: Received fresh labeled ", 10R lymph node". It consists of three soft black-brown anthracotic lymph nodes measuring from 0.2 up to 0.5 cm in greatest dimension. Entirely submitted in 3A.

Source of Tissue: 4. Labeled #4, "right upper lobe"

Intraoperative Consultation: BRONCHIAL MARGIN WITH NO TUMOR SEEN PER [REDACTED]

Gross Description: Received fresh labeled, right upper lobe". It consists of a lobe of lung weighing 197 grams and measuring 14 x 9 x 4 cm. A gray nodular indurated area is identified on the pleura measuring 3 x 2.5 cm in greatest dimension. The bronchial and vascular margins are grossly unremarkable. The specimen is serially sectioned to reveal a 4 x 3.2 x 2.1 cm ill-defined gray mass located approximately 1.5 cm from the bronchial and vascular margins. The mass grossly corresponds to the previously described pleural induration. The remaining lung parenchyma is red-brown, congested with no other masses present. The bronchial margin is frozen in 4FS. Additional random sections of the remainder of the specimen are submitted in 4A-4H.

[page 2 of 3]
Designation of Sections: 4FS- frozen section, 4A- vascular margins, 4B-4E- random section of tumor with closest pleura, 4F- tumor with adjacent normal uninvolved parenchyma, 4G- peribronchial lymph nodes, 4H- uninvolved parenchyma

Source of Tissue: 5. Labeled #5, "level 7 lymph nodes"

TCGA-21-5784

Gross Description: Received fresh labeled ", level 7 lymph nodes". It consists of multiple soft black-brown anthracotic lymph nodes measuring from 0.1 up to 1.5 cm in greatest dimension. The lymph nodes are entirely submitted in 5A-5B.

Source of Tissue: 6. Labeled #6, "level 10 lymph nodes"

Gross Description: Received fresh labeled ", level 10 lymph nodes". It consists of a soft black-brown anthracotic lymph node measuring 0.8 x 0.5 x 0.5 cm. The lymph node is bisected and entirely submitted in 6A.

Source of Tissue: 7. Labeled #7, "level 4R lymph nodes"

Gross Description: Received fresh labeled ", level 4R lymph nodes". It consists of multiple soft black-brown anthracotic lymph nodes measuring from 0.1 up to 0.7 cm in greatest dimension. The lymph nodes are entirely submitted in 7A-7C.

Final Diagnosis:

1. 11R lymph nodes, excision:

- No tumor seen in thirteen lymph nodes (0/13).

2. 3A lymph nodes, excision:

- No tumor seen in three lymph nodes (0/3).

3. 10R lymph nodes, excision:

- No tumor seen in two lymph nodes (0/2).

4. Right lung, upper lobe, lobectomy:

- Squamous cell carcinoma, high grade (4.0 cm).

- Angiolymphatic invasion is not identified.

- Visceral pleura free of tumor.

- Vascular and bronchial margins free of tumor.

- Two peribronchial lymph nodes with no tumor seen (0/2).

5. Level 7 lymph nodes, excision:

- No tumor seen in two lymph nodes (0/2).

6. Level 10 lymph nodes, excision:

- No tumor seen in four lymph nodes (0/4).

7. Level 4R lymph nodes, excision:

- No tumor seen in sixteen lymph nodes (0/16).

[page 3 of 3]
LUNG TEMPLATE

Specimen Type
Lobectomy

Laterality
Right

Tumor Size
Greatest dimension: 4.0 cm (T1 if ≤ 3.0 cm; otherwise T2)

Histologic Type
Squamous cell carcinoma ✓

Histologic Grade
Poorly differentiated

Extension of Tumor
Carcinoma does not involve visceral pleura (T1 unless > 3.0 cm T2)/

Venous (Large Vessel) Invasion
Absent

Arterial (Large Vessel) Invasion
Absent

Margins
Margins uninvolved by invasive carcinoma

Regional Lymph Nodes
32 regional lymph nodes examined
No regional lymph node metastasis

pTNM: T2 N0 Mx

Source: NCI Genomic Data Commons file 31b58364-c5c3-4097-8c23-57190de36af3 (TCGA-21-5784.5D154FAF-BB6E-4237-80CF-9D02E2127ADB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).